Surgical pathology report (de-identified scan), TCGA case TCGA-WK-A8Y0, project TCGA-SARC (Sarcoma), tissue source site Brigham and Women's Hospital, specimen TCGA-WK-A8Y0-01A (Primary Tumor).

[page 1 of 3]
Pathology Report

Accession Number: Report Status: Final
Type: Surgical Pathology
Specimen Type: Soft tissue tumor, extensive resection
Procedure Date:
Ordering Provider:

CASE:

PATIENT: [REDACTED]

Resident:

Pathologist:

PATHOLOGIC DIAGNOSIS:

A. LEFT CHEST WALL SARCOMA, WITH RIBS, PECTORALIS MAJOR, PECTORALIS MINOR,
AND PORTION OF LEFT BREAST:
UNCLASSIFIED PLEOMORPHIC SARCOMA, high grade, 10.2 cm, involving
the fifth rib, intercostal soft tissue, pectoralis muscle, and parietal
pleura.

Focal necrosis of tumor (10%).
Mitoses number 25:10
Lymphovascular invasion identified (block A24).
Tumor extends to the inked pleura surface (block A15).
Rib and soft tissue margins are negative for tumor.
Segment of lung and portion of breast, negative for tumor.
Skin with scar.

The distances of tumor to the resection margins are as follows:

Superior	3.0 cm
Inferior	2.5 cm
3rd rib anterior	4.6 cm
3rd rib posterior	2.7 cm
4th rib anterior	4.5 cm
4th rib posterior	2.6 cm
5th rib anterior	3.4 cm
5th rib posterior	2.9 cm
6th rib anterior	4.1 cm
6th rib posterior	3.8 cm
7th rib anterior	3.9 cm
7th rib posterior	3.1 cm
Anterior soft tissue	2.0 cm
Posterior soft tissue	1.4 cm
Stapled resection margin of lung:	0.9 cm

100-0-3

USE Sarcoma, undifferentiated, pleomorphic 8805/3 8802/3

Code to highest 8805/3

*path Sarcoma, pleomorphic 8802/3
Site: Chest wall C49.3
9/5/14*

AJCC Classification (7th edition): T2 Nx Mx

NOTE:

, of the was reviewed
selected slides of this case and concurs with the above diagnosis.

B. ANTERIOR LEFT UPPER LOBE MARGIN:
Lung parenchyma with minor emphysematous change, negative for tumor.

C. FINAL LEFT UPPER LOBE MARGIN:
Lung with pleural adhesions, negative for tumor.

CLINICAL DATA:

History: Not given.
Operation: Not given.
Operative Findings: Not given.
Clinical Diagnosis: Left chest wall sarcoma.

TISSUE SUBMITTED:

A/1. Left chest wall sarcoma with ribs, pectoralis major, pectoralis minor, and
portion of left breast (white sutures hold lung in approx. to tumor), short

[page 2 of 3]
Pathology Report

black suture superior/long black suture posterior -
B/2. Anterior left upper lobe margin.
C/3. Final left upper lobe margin - stitch marks true margin.

GROSS DESCRIPTION:

The specimen is received in three parts, labeled with the patient's name and MR number.

Part A is labeled "#1. Left chest wall sarcoma with ribs, pectoralis major, pectoralis minor, portion of left breast (three white sutures hold lung in approximation to tumor), short black suture superior/long black suture posterior", and consists of a 533-gram chest wall resection (16.0 x 13.1 x 7.6 cm) with five ribs (ranging from 6.2 to 16.0 cm in length). A portion of lung (5.0 x 4.5 x 0.9 cm) with a stapled resection margin (9.1 cm in length, inked blue), a portion of fibroadipose tissue and muscle (14.8 x 9.4 x 5.6 cm) with an unoriented tan/white skin ellipse (4.2 x 0.6 cm), which exhibits a well-healed linear scar (2.8 cm). The specimen is inked per pathology protocol as anterior-blue, posterior-black, medial-orange, lateral-yellow, superior-red, inferior-green. There is a large firm, focally hemorrhagic and necrotic tan/red mass (10.0 x 7.3 x 4.6 cm) invading to the chest wall and ribs and possibly invading into the breast tissue. The medial surface of the mass is covered by smooth surface consistent with parietal pleura (10.2 x 10.8 x 8.5 cm). A representative section of the mass is allocated for cytogenetics, electron microscopy and tissue bank. A representative section of normal lung is sent for tissue bank. The mass is 4.6 cm to the anterior third rib margin and 2.7 cm to the posterior third rib margin. The mass is 4.5 cm to the fourth rib anterior margin and 2.6 cm to the fourth rib posterior margin, 3.4 cm to the anterior fifth rib margin and 2.9 cm to the posterior fifth rib margin, 4.1 cm to the sixth rib anterior margin, and 3.8 cm to the sixth rib posterior margin, 3.9 cm seventh rib anterior margin and 3.1 cm to the seventh rib posterior margin, 1.4 cm to the posterior soft tissue (between fifth and sixth rib), 2.0 cm to the anterior soft tissue (between third and fourth rib), 0.9 cm to the stapled resection margin of the lung, 3.0 cm to the superior rib margin, and 2.5 cm to the inferior soft tissue margin. On sectioning, the mass extends anterior to the rib and possibly invades beyond the deep muscle into breast. In the breast parenchyma, there is an area of hemorrhage next to the mass, which represents possible invasion. There is also a firm fibrous stroma in the breast (6.0 x 3.0 x 2.0 cm). The mass extensively involves the fifth rib. The fourth and sixth ribs are intact but the surrounding soft tissue is infiltrated by the mass. Representative sections are submitted for histological examination. Gross photographs are taken. The mass was oriented and sections were taken per , soft tissue fellow. The bony sections are submitted after decalcification.

Micro A1: Superior bony margin in third rib, en face, 3 frags,
Micro A2: Anterior fourth rib margin, 1 frag,
Micro A3: Anterior fifth rib margin, 1 frag,
Micro A4: Anterior sixth rib margin, 1 frag,
Micro A5: Anterior seventh rib margin, 1 frag,
Micro A6: Posterior fourth rib margin, 1 frag,
Micro A7: Posterior fifth rib margin, 1 frag,
Micro A8: Posterior sixth rib margin, 1 frag,
Micro A9: Posterior seventh rib margin, 1 frag,
Micro A10: Inferior soft tissue margin, 1 frag,
Micro A11: Soft tissue anteriorly between rib #4 and rib #5, 1 frag,
Micro A12: Soft tissue anteriorly between rib #5 and rib #6, 1 frag,
Micro A13: Soft tissue posteriorly between rib #4 and rib #5, 1 frag,
Micro A14: Soft tissue posteriorly between rib #5 and rib #6, 1 frag,
Micro A15: Medial tumor to pleura margin, 1 frag,
Micro A16: Lateral breast plus skin margin, 1 frag,
Micro A17: Possible invasion into breast, 1 frag,
Micro A18: Tumor in relation to breast, 1 frag,
Micro A19: Fibrous stroma of breast, 1 frag,
Micro A20: Fibrous stroma of breast, 1 frag,
Micro A21: Tumor to fractured fifth rib, 1 frag,
Micro A22: Tumor to intact sixth rib, 1 frag,
Micro A23: Tumor to intact part of fifth rib, 1 frag,
Micro A24: Tumor to fourth rib, 1 frag,

[page 3 of 3]
Sex:F

Pathology Report

Micro A25-A30: Representative sections of tumor, 2 frags each,
Micro A31: Lung adherent to tumor, 1 frag.
Micro A32-A33: Lung margin, 1 frag each,

Part B is labeled "#2. Right anterior, left upper lobe margin", and consists of a segment of lung (4.0 x 2.5 x 1.0 cm) with a stapled resection margin (4.0 cm, inked blue). No lesions are grossly identified. Representative sections are submitted for histological examination.

Micro B1: Lung margin, 1 frag,

Part C is labeled "#3. Final left upper lobe margin - stitch marks true margin", and consists of a 27.5-gram lung wedge resection (9.1 x 3.4 x 2.5 cm) with two stapled resection margins (9.1 cm with stitch, inked blue and 4.5 cm stapled resection margin, inked black). No lesions are grossly identified. Representative sections are submitted for histological examination.

Micro C1-C2: Lung margin, 1 frag each,

CASE NUMBER:

By his/her signature below, the senior physician certifies that he/she personally conducted a microscopic examination ("gross only" exam if so stated) of the described specimen(s) and rendered or confirmed the diagnosis(es) related thereto.

Final Diagnosis by

, Electronically signed on

Source: NCI Genomic Data Commons file 8388b859-099f-49ab-a771-4aa3a3fa512d (TCGA-WK-A8Y0.CD5D0087-8658-4F08-B6EC-52D67A5F514D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).